Somatic mutation profile of tumor specimen 0DYJ24 from CCDI case PBCSSR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Teratoma, NOS; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 11.4 years (4,153 days).
Specimen 0DYJ24: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 964c6f3c-d084-4483-a8fa-2ab64f20f3d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYJ1X (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c202fdf-c593-442c-8836-a434313ef118

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTGFRN | c.1309G>T p.G437W | Missense Mutation (SNP) | VAF 162/527 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as rs759528919; called by muse, varscan2
- MAD2L1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 193/678 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); called by muse, varscan2
- CD244 | c.976-26G>A | Intron (SNP) | VAF 146/252 reads (58%) | called by muse, varscan2
- GAS6 | c.-42C>A | 5'UTR (SNP) | VAF 3/11 reads (27%) | called by muse, varscan2
